MMRF case MMRF_2373 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d198b031-271b-42d7-8a02-69ce094b148a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 542 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.1 years (24,525 days); ISS stage: I; Days to last known disease status: 542 days (1.5 years); Days to last follow up: 542 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 146 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 274 days; Days to treatment end: 351 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 274 days; Days to treatment end: 515 days (1.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 361 days; Days to treatment end: 515 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 542.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 467 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.593 mg/dL; Immunoglobulin G 4.44 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.15 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.05 mg/dL.
- Day 79: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 133 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.784 mg/dL; Immunoglobulin G 2.34 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 4.46 mmol/L.
- Day 170 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 150 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.757 mg/dL; Immunoglobulin G 3.12 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 5.12 mmol/L.
- Day 274 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 153 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.148 mg/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.17 mmol/L.
- Day 361 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.168 mg/dL; Immunoglobulin G 2.8 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 5.4 g/dL; Glucose 4.79 mmol/L.
- Day 443 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 226 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.642 mg/dL; Immunoglobulin G 2.33 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.85 ×10⁹/L; Platelets 38 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 5.3 g/dL; Glucose 8.8 mmol/L.

Other clinical attributes
- Day -12: Weight: 63 kg; Height: 167 cm.

Biospecimens (3 samples)
- Sample MMRF_2373_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2373_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
- Sample MMRF_2373_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 443 days (1.2 years).
